CPTAC case C3L-03748 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/097d76e4-0811-4ac5-85b8-4e3704e8d6c2

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1953; Vital status: Dead; Days to death: 401 days (1.1 years); Year of death: 2019; Cause of death: Cancer Related; Country of birth: United States.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Frontal lobe; Age at diagnosis: 65.0 years (23,735 days); Year of diagnosis: 2018; Last known disease status: With tumor; Days to last known disease status: 401 days (1.1 years); Progression or recurrence: yes; Days to recurrence: 162 days; Days to last follow up: 397 days (1.1 years).
   Pathology details: Greatest tumor dimension: 6 cm.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.

Follow-up (2 entries)
- Days to follow up: 397 days (1.1 years); Disease response: With Tumor; Progression or recurrence: Yes; Days to recurrence: 162 days; Karnofsky performance status: 0; ECOG performance status: 5.
- Follow-up contact recording only the day: day 328.

Other clinical attributes
- Weight: 67.59 kg; Height: 165.1 cm; BMI: 24.79.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-03748-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -5 days; Initial weight: 209 mg; Time between excision and freezing: 24 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-03748-24: Section location: Frontal Lobe; Percent tumor nuclei: 70; Percent necrosis: 20.
- Sample C3L-03748-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -5 days; Method of sample procurement: Blood Draw.
